Somatic mutation profile of tumor specimen TCGA-ZF-A9R2-01A (aliquot TCGA-ZF-A9R2-01A-11D-A391-08) from TCGA case TCGA-ZF-A9R2, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 75.4 years (27,537 days).
Specimen TCGA-ZF-A9R2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 68829af9-3c54-47e4-acb0-7716169823f1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZF-A9R2-10A (Blood Derived Normal), aliquot TCGA-ZF-A9R2-10A-01D-A394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/095320d2-1002-4686-a175-26b6a035fd4d

The open-access MAF lists 164 somatic variants for this specimen: 119 protein-altering or splice-affecting, 40 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 106, Silent 40, Nonsense Mutation 8, Splice Site 3, Splice Region 2, RNA 1, 5'UTR 1, Intron 1, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR3 | c.746C>G p.S249C | Missense Mutation (SNP) | VAF 26/29 reads (90%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913483, CM950470, COSV53390026; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAM20 | c.919A>G p.K307E | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.012); catalogued as COSV56455902; called by muse, mutect2, varscan2
- ANK2 | c.4804G>C p.E1602Q | Missense Mutation (SNP) | VAF 62/75 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52178054; called by muse, mutect2, varscan2
- ANK3 | c.12817G>T p.D4273Y (on ENST00000280772 / NM_001320874.2; = p.D897Y on NM_001149.3) | Missense Mutation (SNP) | VAF 50/153 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV55061500, COSV55072568; called by muse, mutect2, varscan2
- ANKS3 | c.1890G>C p.E630D | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.112); catalogued as COSV58510373; called by muse, mutect2, varscan2
- ARHGAP21 | c.1742C>T p.S581L | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.162); catalogued as rs1291381409, COSV57609423; called by muse, mutect2, varscan2
- ATF7 | c.1265T>G p.L422* (on ENST00000548446 / NM_001366555.2; = p.L411* on NM_006856.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 25/55 reads (45%) | catalogued as COSV100129796; called by muse, varscan2
- BICC1 | c.238-1del p.X80_splice | Splice Site (DEL) | VAF 10/36 reads (28%) | catalogued as COSV65863130; called by mutect2, pindel, varscan2
- BIRC6 | c.3178C>G p.Q1060E | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV70203595; called by muse, mutect2, varscan2
- BPIFA1 | c.753G>C p.Q251H | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.258); catalogued as COSV62824946; called by muse, mutect2, varscan2
- C5orf49 | c.151G>A p.G51R | Missense Mutation (SNP) | VAF 48/90 reads (53%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.979); catalogued as rs1340609565, COSV67709238; called by muse, mutect2, varscan2
- CAPN7 | c.242C>A p.S81* | Nonsense Mutation (SNP) | VAF 31/63 reads (49%) | catalogued as COSV99513057; called by muse, mutect2, varscan2
- CARNMT1 | c.620C>G p.P207R | Missense Mutation (SNP) | VAF 48/67 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV65193643, COSV65194208; called by muse, mutect2, varscan2
- CBX4 | c.1632C>G p.D544E | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53966963, COSV53967120; called by muse, mutect2, varscan2
- CCDC68 | c.875A>G p.N292S | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.103); catalogued as COSV61604434; called by muse, mutect2, varscan2
- CCR10 | c.958G>A p.D320N | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.716); catalogued as COSV99227044; called by muse, mutect2, varscan2
- CCRL2 | c.112G>C p.A38P | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.049); catalogued as COSV62193905; called by muse, mutect2, varscan2
- CDKN1A | c.146G>A p.W49* | Nonsense Mutation (SNP) | VAF 28/37 reads (76%) | catalogued as rs1260849045, COSV55187626, COSV99781593; called by muse, mutect2, varscan2
- CDKN1A | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 10/10 reads (100%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV55190528; called by muse, varscan2
- CDKN1A | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT tolerated (0.15); PolyPhen benign (0.358); catalogued as COSV55190544; called by muse, mutect2, varscan2
- CHRM2 | c.1054C>G p.Q352E | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.94); PolyPhen benign (0.006); catalogued as COSV57764934, COSV57779645; called by muse, mutect2, varscan2
- CSE1L | c.2616G>C p.L872F | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53703858; called by muse, mutect2, varscan2
- DCAKD | c.73G>A p.G25S | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60202929; called by muse, mutect2, varscan2
- DKK2 | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); catalogued as COSV53401085; called by muse, mutect2
- DOCK10 | c.2936A>G p.D979G | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.352); catalogued as rs1377038975, COSV51422662; called by muse, mutect2, varscan2
- DYNC1H1 | c.11584G>C p.D3862H | Missense Mutation (SNP) | VAF 36/64 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV64140144; called by muse, varscan2
- EIF3A | c.3865C>G p.L1289V | Missense Mutation (SNP) | VAF 72/146 reads (49%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as COSV64962492; called by muse, mutect2, varscan2
- EIF3I | c.396G>C p.Q132H | Missense Mutation (SNP) | VAF 48/93 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV59084058; called by muse, mutect2, varscan2
- ELP1 | c.2701G>C p.D901H | Missense Mutation (SNP) | VAF 28/36 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV65897847; called by muse, mutect2, varscan2
- ERICH1 | c.859G>T p.E287* | Nonsense Mutation (SNP) | VAF 74/185 reads (40%) | catalogued as COSV100033095; called by muse, mutect2, varscan2
- ESPL1 | c.3184A>G p.T1062A | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV57761532; called by muse, mutect2, varscan2
- EXOC7 | c.331G>C p.E111Q | Missense Mutation (SNP) | VAF 61/134 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.344); catalogued as COSV58743678; called by muse, mutect2, varscan2
- EXOC7 | c.286G>A p.D96N | Missense Mutation (SNP) | VAF 74/152 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as COSV58743695; called by muse, mutect2, varscan2
- FAM160B2 | c.2194C>G p.R732G | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.015); catalogued as COSV57159391, COSV57159778; called by muse, mutect2, varscan2
- FFAR3 | c.170T>C p.L57P | Missense Mutation (SNP) | VAF 17/162 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59909451; called by muse, mutect2
- FLRT2 | c.1045G>T p.A349S | Missense Mutation (SNP) | VAF 97/161 reads (60%) | SIFT tolerated (0.1); PolyPhen benign (0.091); catalogued as rs1416415206, COSV58147096; called by muse, mutect2, varscan2
- FYN | c.447G>C p.W149C | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57618291; called by muse, mutect2, varscan2
- GPR158 | c.2725G>A p.A909T | Missense Mutation (SNP) | VAF 68/125 reads (54%) | SIFT tolerated (0.09); PolyPhen benign (0.391); catalogued as rs767899224, COSV66269686; called by muse, mutect2, varscan2
- H1-8 | c.775G>C p.E259Q | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as COSV100140627, COSV60717207; called by muse, mutect2, varscan2
- HEATR4 | c.2164G>C p.E722Q | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.173); catalogued as COSV58575704; called by muse, mutect2, varscan2
- HNRNPD | c.410C>G p.S137* | Nonsense Mutation (SNP) | VAF 100/122 reads (82%) | catalogued as COSV100003086; called by muse, mutect2, varscan2
- HPS3 | c.2297T>G p.L766R | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56056319; called by muse, mutect2, varscan2
- HTR1F | c.125C>G p.S42C | Missense Mutation (SNP) | VAF 86/178 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV60390794, COSV60391226; called by muse, mutect2, varscan2
- HTR3D | c.1207G>A p.E403K (on ENST00000382489 / NM_001163646.2; = p.E228K on NM_182537.3) | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0.105); catalogued as COSV100488032; called by muse, varscan2
- IBSP | c.247G>C p.E83Q | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.798); catalogued as COSV56896652; called by muse, mutect2, varscan2
- IGSF10 | c.6562G>C p.D2188H | Missense Mutation (SNP) | VAF 67/134 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.859); catalogued as COSV56389723; called by muse, mutect2, varscan2
- INO80 | c.3067G>T p.D1023Y | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.328); catalogued as COSV62740921; called by muse, mutect2, varscan2
- KALRN | c.448G>C p.E150Q | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53772534; called by muse, mutect2, varscan2
- KASH5 | c.1503G>C p.R501S | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as COSV71358234; called by muse, mutect2, varscan2
- KDM6A | c.655-2A>G p.X219_splice | Splice Site (SNP) | VAF 30/40 reads (75%) | catalogued as COSV65043565; called by muse, varscan2
- KRT19 | c.919G>C p.E307Q | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54181045; called by muse, mutect2, varscan2
- LDLRAP1 | c.216G>C p.K72N | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV65474006; called by muse, mutect2, varscan2
- LPCAT2 | c.1616C>G p.S539* | Nonsense Mutation (SNP) | VAF 21/75 reads (28%) | catalogued as rs1246513043, COSV100045341; called by muse, mutect2, varscan2
- LRP1 | c.11285A>G p.N3762S | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.389); catalogued as rs764479936, COSV54520049; called by muse, mutect2, varscan2
- MAP3K4 | c.4036G>A p.G1346R | Missense Mutation (SNP) | VAF 34/52 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62336540; called by muse, mutect2, varscan2
- MRC1 | c.1182A>C p.E394D | Missense Mutation (SNP) | VAF 48/235 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.892); catalogued as COSV53470832; called by muse, mutect2, varscan2
- MTERF1 | c.61A>G p.M21V | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); catalogued as rs766900295, COSV61098863; called by muse, mutect2, varscan2
- MUC16 | c.22012G>A p.E7338K | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.027); catalogued as COSV67481394; called by muse, mutect2, varscan2
- MYH13 | c.4232C>T p.A1411V | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs757283120, COSV52836977, COSV52847475; called by muse, mutect2, varscan2
- MYOM1 | c.4844C>T p.S1615L | Missense Mutation (SNP) | VAF 26/36 reads (72%) | SIFT tolerated (0.63); PolyPhen benign (0.412); catalogued as COSV55289457, COSV55297548; called by muse, mutect2, varscan2
- NAV3 | c.407C>T p.S136F | Missense Mutation (SNP) | VAF 11/132 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57100478; called by muse, mutect2
- NAV3 | c.3239C>G p.T1080S | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV57100494; called by muse, mutect2, varscan2
- NGDN | c.10C>T p.L4= | Splice Region (SNP) | VAF 12/53 reads (23%) | catalogued as rs781427672, COSV68142750; called by muse, mutect2, varscan2
- NRP1 | c.1037C>T p.S346L | Missense Mutation (SNP) | VAF 48/78 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55173343; called by muse, mutect2, varscan2
- OAS1 | c.1132C>T p.H378Y | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.012); catalogued as rs865959783, COSV52537627; called by muse, mutect2, varscan2
- OPRK1 | c.956G>T p.G319V | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55572641, COSV55572689; called by muse, mutect2, varscan2
- OR2B6 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 132/160 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55129545; called by muse, mutect2, varscan2
- PDZRN4 | c.1804T>C p.Y602H (on ENST00000402685 / NM_001164595.2; = p.Y344H on NM_013377.4) | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0.254); catalogued as COSV54210771; called by muse, mutect2, varscan2
- PIK3CA | c.2128G>C p.E710Q | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.203); catalogued as COSV55963395; called by muse, varscan2
- PLXNB1 | c.1561G>C p.E521Q | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.409); catalogued as rs1222715824, COSV56492554; called by muse, mutect2, varscan2
- PNPLA1 | c.1360G>C p.E454Q (on ENST00000394571 / NM_001374623.1; = p.E359Q on NM_173676.2) | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.099); catalogued as COSV57236580; called by muse, mutect2, varscan2
- POLG2 | c.441A>T p.L147F | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as COSV56750499; called by muse, mutect2, varscan2
- PPID | c.261C>G p.F87L | Missense Mutation (SNP) | VAF 39/52 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV56988696; called by muse, mutect2, varscan2
- PPM1D | c.1652G>C p.R551T | Missense Mutation (SNP) | VAF 51/103 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.205); catalogued as COSV59957000; called by muse, mutect2, varscan2
- RALGAPA1 | c.4444G>A p.E1482K | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0.379); catalogued as COSV51891210; called by muse, mutect2, varscan2
- RASAL1 | c.826G>C p.E276Q | Missense Mutation (SNP) | VAF 56/122 reads (46%) | SIFT tolerated (0.61); PolyPhen benign (0.01); catalogued as COSV55658391; called by muse, mutect2, varscan2
- RBBP6 | c.426C>G p.Y142* | Nonsense Mutation (SNP) | VAF 9/98 reads (9%) | catalogued as COSV100154990, COSV60503182; called by muse, mutect2
- RC3H1 | c.1274G>C p.R425T | Missense Mutation (SNP) | VAF 47/137 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.848); catalogued as COSV51204994, COSV51208179; called by muse, mutect2, varscan2
- RFC2 | c.259C>G p.L87V | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.85); catalogued as COSV50016628; called by muse, mutect2, varscan2
- RHEX | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 72/187 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as COSV58980412, COSV58981439; called by muse, mutect2, varscan2
- RPN2 | c.1652C>A p.S551* | Nonsense Mutation (SNP) | VAF 69/176 reads (39%) | catalogued as COSV99412096; called by muse, mutect2, varscan2
- RSRP1 | c.160T>G p.S54A | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.164); catalogued as COSV54562884; called by muse, mutect2, varscan2
- RYR2 | c.221C>G p.S74C | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63702659, COSV63709433; called by muse, mutect2, varscan2
- SAMD15 | c.1072C>T p.P358S | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.063); catalogued as COSV53627319; called by muse, mutect2, varscan2
- SAMHD1 | c.80C>T p.S27F | Missense Mutation (SNP) | VAF 137/321 reads (43%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.007); catalogued as COSV53429797; called by muse, mutect2, varscan2
- SCN1A | c.1888C>T p.R630W | Missense Mutation (SNP) | VAF 34/56 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs565855062, CM1414496, COSV57674282; ClinVar: likely benign; called by muse, mutect2, varscan2
- SHMT1 | c.466G>C p.D156H | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as COSV57399952; called by muse, mutect2, varscan2
- SLC24A5 | c.265G>C p.E89Q | Missense Mutation (SNP) | VAF 74/155 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV58318514; called by muse, mutect2, varscan2
- SLC26A5 | c.1390A>G p.T464A | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.062); catalogued as COSV59698346; called by muse, mutect2, varscan2
- SLC8A2 | c.608C>G p.S203C | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.87); catalogued as COSV52641731; called by muse, mutect2, varscan2
- SRCAP | c.7504C>T p.P2502S | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.025); catalogued as rs759964374, COSV99351385; called by muse, mutect2, varscan2
- TAOK2 | c.904C>T p.R302W | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV54233266; called by mutect2, varscan2
- TAP1 | c.173G>C p.R58P | Missense Mutation (SNP) | VAF 24/26 reads (92%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV62755303; called by muse, mutect2, varscan2
- TKTL2 | c.620G>T p.C207F | Missense Mutation (SNP) | VAF 87/106 reads (82%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.994); catalogued as COSV54920514; called by muse, mutect2, varscan2
- TMEM94 | c.1718C>G p.S573C | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.159); catalogued as COSV58598570, COSV58600734; called by muse, mutect2, varscan2
- TRIM42 | c.131A>G p.Y44C | Missense Mutation (SNP) | VAF 19/176 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV53885310; called by muse, mutect2, varscan2
- TSHR | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs1192804611, COSV53327200; called by muse, mutect2
- TTC37 | c.1091C>T p.S364L | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV62456004; called by muse, mutect2
- TTN | c.30794C>G p.P10265R (on ENST00000591111; = p.P9338R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/54 reads (28%) | PolyPhen benign (0.031); catalogued as COSV60228869; called by muse, mutect2, varscan2
- TXNDC12 | c.413A>G p.K138R | Missense Mutation (SNP) | VAF 50/93 reads (54%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.492); catalogued as COSV65413857; called by muse, mutect2, varscan2
- UBXN6 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as rs1048806686, COSV56674971; called by muse, mutect2, varscan2
- VPS41 | c.814A>G p.S272G | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT tolerated (0.44); PolyPhen benign (0.108); catalogued as COSV59651577; called by muse, mutect2, varscan2
- VSTM1 | c.644C>G p.S215C | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV58076011; called by muse, mutect2, varscan2
- VSTM4 | c.317G>T p.R106L | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV53676987, COSV53678021, COSV53678827; called by muse, mutect2, varscan2
- VWA3A | c.2662C>T p.H888Y | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.085); catalogued as COSV55393740; called by muse, mutect2, varscan2
- WDR74 | c.519G>T p.V173= | Splice Region (SNP) | VAF 29/43 reads (67%) | catalogued as COSV53681078; called by muse, mutect2, varscan2
- WNK3 | c.3984G>C p.M1328I | Missense Mutation (SNP) | VAF 44/54 reads (81%) | SIFT tolerated (0.16); PolyPhen benign (0.437); catalogued as COSV63615245; called by muse, mutect2, varscan2
- XIRP1 | c.1084G>C p.E362Q | Missense Mutation (SNP) | VAF 66/192 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as COSV61140032; called by muse, mutect2, varscan2
- ZEB1 | c.2881C>G p.Q961E | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.981); catalogued as rs1002948043, COSV58048865, COSV58050824; called by muse, mutect2, varscan2
- ZFHX3 | c.2312G>T p.G771V | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.973); catalogued as rs777386793, COSV51728675; called by muse, varscan2
- ZNF212 | c.956C>T p.S319F | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.483); catalogued as COSV60024698, COSV60025720; called by muse, mutect2, varscan2
- ZNF318 | c.4117C>G p.L1373V | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs771310923, COSV58935446; called by muse, mutect2, varscan2
- ZNF337 | c.1222G>T p.D408Y | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.144); catalogued as rs1190721564, COSV53322537; called by muse, mutect2, varscan2
- ZNF546 | c.1410A>T p.E470D | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV61258757; called by muse, mutect2
- ZRANB2 | c.551A>G p.N184S | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.074); catalogued as COSV54673417; called by muse, mutect2, varscan2
- ACACA | c.1294A>G p.I432V | Missense Mutation (SNP) | VAF 26/351 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.065); called by muse, mutect2
- EDAR | c.963+1dup p.X321_splice | Splice Site (INS) | VAF 10/97 reads (10%) | called by mutect2, pindel, varscan2
- OR11H1 | c.922G>C p.V308L | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.012); called by mutect2, varscan2
- SALL3 | c.2467C>G p.L823V | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.023); called by muse, varscan2
- ADAMTS18 | c.2886G>A p.K962= | Silent (SNP) | VAF 36/82 reads (44%) | catalogued as COSV51420357; called by muse, mutect2, varscan2
- ASCC3 | c.2367G>A p.Q789= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV61231691; called by muse, mutect2, varscan2
- CCDC151 | c.559C>T p.L187= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as rs1283617925, COSV62698703; called by muse, mutect2, varscan2
- CCR10 | c.957G>A p.Q319= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as rs1437557705, COSV99227045; called by muse, mutect2, varscan2
- CEP97 | c.547C>A p.R183= | Silent (SNP) | VAF 58/138 reads (42%) | catalogued as COSV59123774, COSV59126530; called by muse, mutect2, varscan2
- CR1L | c.1605C>T p.S535= | Silent (SNP) | VAF 20/139 reads (14%) | catalogued as rs1177603252, COSV54325723, COSV54329447; called by muse, mutect2, varscan2
- CT83 | c.123G>C p.V41= | Silent (SNP) | VAF 56/63 reads (89%) | catalogued as COSV64141308; called by muse, mutect2, varscan2
- DKK2 | c.636A>G p.E212= | Silent (SNP) | VAF 13/172 reads (8%) | catalogued as COSV53401077, COSV53403476; called by muse, mutect2
- DYNC1H1 | c.11538G>C p.L3846= | Silent (SNP) | VAF 26/50 reads (52%) | catalogued as COSV64140137; called by muse, varscan2
- ERICH3 | c.3384C>T p.N1128= | Silent (SNP) | VAF 35/109 reads (32%) | catalogued as rs769950814, COSV58613714; called by muse, mutect2, varscan2
- FBF1 | c.3401G>A p.*1134= (on ENST00000586717; = p.*1149= on NM_001319193.1) | Silent (SNP) | VAF 5/9 reads (56%) | catalogued as rs573707995, COSV100045608; called by muse, varscan2
- FLNC | c.2040C>A p.T680= | Silent (SNP) | VAF 50/195 reads (26%) | catalogued as COSV57961132; called by muse, mutect2, varscan2
- GOLGB1 | c.255G>A p.E85= | Silent (SNP) | VAF 50/119 reads (42%) | catalogued as COSV61468824; called by muse, mutect2, varscan2
- ITPA | c.114G>A p.Q38= | Silent (SNP) | VAF 72/218 reads (33%) | catalogued as COSV66318746; called by muse, mutect2
- KCTD18 | c.48G>T p.L16= | Silent (SNP) | VAF 33/52 reads (63%) | catalogued as COSV63344932; called by muse, mutect2, varscan2
- LPCAT1 | c.1335C>G p.L445= | Silent (SNP) | VAF 25/82 reads (30%) | catalogued as COSV52039457, COSV52039935; called by muse, mutect2, varscan2
- MAGED1 | c.1584G>A p.L528= | Silent (SNP) | VAF 16/16 reads (100%) | catalogued as COSV58516185, COSV58517196; called by muse, mutect2, varscan2
- MARS1 | c.159G>A p.L53= | Silent (SNP) | VAF 55/159 reads (35%) | catalogued as COSV56257426; called by muse, mutect2, varscan2
- MROH7 | c.3591C>T p.F1197= | Silent (SNP) | VAF 7/134 reads (5%) | catalogued as COSV64887923; called by muse, mutect2
- MUC16 | c.41532G>A p.L13844= | Silent (SNP) | VAF 30/88 reads (34%) | catalogued as COSV66695026; called by muse, mutect2, varscan2
- NAA11 | c.171G>T p.L57= | Silent (SNP) | VAF 25/196 reads (13%) | catalogued as COSV54515356; called by muse, mutect2, varscan2
- NKIRAS2 | c.129C>T p.Y43= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as rs781973161, COSV56918243; called by muse, mutect2, varscan2
- OR4C6 | c.393G>A p.T131= | Silent (SNP) | VAF 63/81 reads (78%) | catalogued as rs1218031042, COSV58602697, COSV58605476; called by muse, mutect2, varscan2
- OR4Q3 | c.372G>A p.L124= | Silent (SNP) | VAF 35/70 reads (50%) | catalogued as COSV59179652; called by muse, mutect2, varscan2
- PLCXD1 | c.147G>T p.T49= | Silent (SNP) | VAF 46/128 reads (36%) | catalogued as COSV67542362; called by muse, mutect2, varscan2
- RIMS3 | c.57G>A p.R19= | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as COSV65505084; called by muse, mutect2, varscan2
- SRRM2 | c.930C>T p.F310= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as rs947419328, COSV57078049; called by muse, mutect2, varscan2
- SUGP1 | c.381C>T p.L127= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as rs1292825088, COSV55923004; called by muse, mutect2, varscan2
- TAF6L | c.1164G>A p.G388= | Silent (SNP) | VAF 13/19 reads (68%) | catalogued as rs1326622778, COSV53670205; called by muse, mutect2, varscan2
- TALDO1 | c.759C>T p.L253= | Silent (SNP) | VAF 55/67 reads (82%) | catalogued as rs1564994638, COSV59798163; called by muse, mutect2, varscan2
- TAS1R2 | c.1923C>T p.F641= | Silent (SNP) | VAF 25/104 reads (24%) | catalogued as COSV64746274; called by muse, mutect2, varscan2
- TBC1D23 | c.1518C>T p.I506= | Silent (SNP) | VAF 21/57 reads (37%) | catalogued as rs748159443, COSV61369502; called by muse, mutect2, varscan2
- TMEM59L | c.483C>T p.V161= | Silent (SNP) | VAF 67/126 reads (53%) | catalogued as COSV53243035; called by muse, mutect2, varscan2
- TP63 | c.1698G>C p.T566= | Silent (SNP) | VAF 65/157 reads (41%) | catalogued as rs1425837540, COSV53211492, COSV53215150; called by muse, mutect2, varscan2
- TRAF7 | c.636C>T p.F212= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV58217060; called by muse, mutect2, varscan2
- TRPC5 | c.2670A>G p.K890= | Silent (SNP) | VAF 45/53 reads (85%) | catalogued as COSV53298581; called by muse, mutect2, varscan2
- ZMYM4 | c.2931C>T p.P977= | Silent (SNP) | VAF 80/183 reads (44%) | catalogued as COSV58914579; called by muse, mutect2, varscan2
- ZNF134 | c.798G>C p.G266= | Silent (SNP) | VAF 18/160 reads (11%) | catalogued as COSV68696314, COSV68696639; called by muse, mutect2, varscan2
- ZNF496 | c.234G>A p.K78= | Silent (SNP) | VAF 29/57 reads (51%) | catalogued as COSV54174339; called by muse, mutect2, varscan2
- ZNF84 | c.1959G>A p.K653= | Silent (SNP) | VAF 32/256 reads (13%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73845972 A>T | 5'Flank (SNP) | VAF 61/76 reads (80%) | catalogued as rs1202850952; called by muse, mutect2, varscan2
- AMFR | c.*149G>C | 3'UTR (SNP) | VAF 6/31 reads (19%) | catalogued as COSV99316244; called by muse, mutect2, varscan2
- SSPOP | n.2777C>T | RNA (SNP) | VAF 24/94 reads (26%) | catalogued as rs1224847319, COSV50486280, COSV50487764; called by muse, mutect2, varscan2
- TBC1D12 | c.-1G>A | 5'UTR (SNP) | VAF 16/31 reads (52%) | catalogued as rs762145762, COSV56552290, COSV56558736; called by muse, mutect2, varscan2
- UBAC2 | c.808-11633C>T | Intron (SNP) | VAF 65/241 reads (27%) | catalogued as rs757376877, COSV63122673; called by muse, mutect2, varscan2
